TARGET case TARGET-30-PALAWZ — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/e81104bb-6b25-55a0-95a8-43f9d469cdef

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Medulla of adrenal gland; Age at diagnosis: 3.7 years (1,338 days); Year of diagnosis: 2001; Days to last follow up: 956 days (2.6 years); INSS stage: Stage 4.

Biospecimens (1 sample)
- Sample TARGET-30-PALAWZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
